HCMI case HCM-CSHL-0634-C30 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Nasal cavity and middle ear. Index date (day 0 for every day count below): first patient visit.
https://portal.gdc.cancer.gov/cases/9ffb2777-3c88-4ee4-bb86-956c7c4fb6c4

Demographics
Sex at birth: male; Days to birth: -20,805 days (57.0 years before the index date); Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C30.0; Tissue or organ of origin: Nasal cavity; Site of resection or biopsy: Nasal cavity; Laterality: Right; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; Tumor grade: G1; Prior malignancy: no; Prior treatment: No; Tumor focality: Unifocal.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 39 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 67 days; Days to treatment end: 103 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 320 days; Disease response: Complete Response; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 176 cm; BMI: 25.5.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Alcohol intensity: Drinker; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-CSHL-0634-C30-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-CSHL-0634-C30-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
